Somatic mutation profile of tumor specimen TCGA-IB-7891-01A (aliquot TCGA-IB-7891-01A-11D-2201-08) from TCGA case TCGA-IB-7891, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G1; Age at diagnosis: 49.8 years (18,202 days).
Specimen TCGA-IB-7891-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9ebf4af2-1535-4185-b7fb-35ec0e0557fb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-IB-7891-10A (Blood Derived Normal), aliquot TCGA-IB-7891-10A-01D-2201-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f146d4e0-ac70-4677-b553-961b1b102596

The open-access MAF lists 27 somatic variants for this specimen: 21 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 17, Silent 6, Nonsense Mutation 2, Frame Shift Ins 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.734G>T p.G245V | Missense Mutation (SNP) | VAF 37/363 reads (10%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121912656, CM010464, CM900209, COSV52666323, COSV52667838, COSV52745465; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- AURKA | c.915G>A p.M305I | Missense Mutation (SNP) | VAF 34/387 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.059); catalogued as COSV100452862; called by muse, mutect2
- CASP8 | c.106G>T p.E36* | Nonsense Mutation (SNP) | VAF 33/316 reads (10%) | catalogued as COSV51848718; called by muse, mutect2, varscan2
- EFTUD2 | c.381G>C p.E127D | Missense Mutation (SNP) | VAF 33/446 reads (7%) | SIFT tolerated (0.41); PolyPhen benign (0.005); catalogued as COSV101274523; called by muse, mutect2
- FLNA | c.5933C>A p.T1978K (on ENST00000369850 / NM_001110556.2; = p.T1970K on NM_001456.3) | Missense Mutation (SNP) | VAF 34/548 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.017); catalogued as COSV100774409; called by muse, mutect2
- HOXD13 | c.955C>T p.Q319* | Nonsense Mutation (SNP) | VAF 20/382 reads (5%) | catalogued as COSV101184174; called by muse, mutect2
- KRTAP6-2 | c.92G>A p.R31H | Missense Mutation (SNP) | VAF 31/354 reads (9%) | PolyPhen benign (0.007); catalogued as rs980515366, COSV100588896; called by muse, mutect2
- LRRK1 | c.3856+1G>T p.X1286_splice | Splice Site (SNP) | VAF 16/198 reads (8%) | catalogued as COSV99438300; called by muse, mutect2
- MICAL2 | c.3082C>T p.R1028C | Missense Mutation (SNP) | VAF 32/395 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.024); catalogued as rs751050743, COSV99816915; called by muse, mutect2
- MYO10 | c.3781G>A p.V1261I | Missense Mutation (SNP) | VAF 66/984 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs375436981; called by muse, mutect2
- NLRP8 | c.729C>A p.F243L | Missense Mutation (SNP) | VAF 128/784 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.03); catalogued as rs1307644718, COSV99404899; called by muse, mutect2, varscan2
- NTRK1 | c.2104C>T p.R702C | Missense Mutation (SNP) | VAF 49/489 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs374918502; called by muse, mutect2, varscan2
- PCDHGA7 | c.2168G>A p.R723H | Missense Mutation (SNP) | VAF 26/343 reads (8%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.009); catalogued as rs963028251, COSV99533603; called by muse, mutect2
- SCN9A | c.583G>A p.V195I | Missense Mutation (SNP) | VAF 42/423 reads (10%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.996); catalogued as rs775461240, COSV57604465; called by muse, mutect2, varscan2
- SMAD4 | c.326T>A p.L109Q | Missense Mutation (SNP) | VAF 40/480 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100747568, COSV61685097; called by muse, mutect2
- SPACA3 | c.44C>T p.S15L | Missense Mutation (SNP) | VAF 31/514 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.185); catalogued as COSV99284131; called by muse, mutect2
- TASOR2 | c.2944G>A p.D982N | Missense Mutation (SNP) | VAF 30/422 reads (7%) | SIFT tolerated (0.18); PolyPhen benign (0.02); catalogued as rs778866633, COSV100050120; called by muse, mutect2
- TNC | c.697A>G p.N233D | Missense Mutation (SNP) | VAF 22/408 reads (5%) | SIFT tolerated (0.59); PolyPhen benign (0.003); catalogued as COSV100405259; called by muse, mutect2
- XYLT1 | c.2344G>A p.V782I | Missense Mutation (SNP) | VAF 42/451 reads (9%) | SIFT tolerated (0.42); PolyPhen benign (0.355); catalogued as rs778581218, COSV54483040; called by muse, mutect2
- ZNF486 | c.745T>A p.Y249N | Missense Mutation (SNP) | VAF 23/317 reads (7%) | SIFT tolerated (0.32); PolyPhen benign (0.281); catalogued as COSV100631138; called by muse, mutect2
- KMT2D | c.7780dup p.L2594Pfs*61 | Frame Shift Ins (INS) | VAF 12/106 reads (11%) | called by mutect2, pindel
- GRIN2B | c.3156C>T p.H1052= | Silent (SNP) | VAF 16/182 reads (9%) | catalogued as rs543452359, COSV101662963; called by muse, mutect2
- PCDHB1 | c.873G>A p.T291= | Silent (SNP) | VAF 30/330 reads (9%) | catalogued as rs1172005666, COSV60631017; called by muse, mutect2
- PPEF1 | c.585G>A p.P195= | Silent (SNP) | VAF 86/1131 reads (8%) | catalogued as rs759551640, COSV62995107; called by muse, mutect2
- SYNE1 | c.3897G>A p.A1299= (on ENST00000367255 / NM_182961.4; = p.A1306= on NM_033071.3) | Silent (SNP) | VAF 26/424 reads (6%) | catalogued as COSV55034127; called by muse, mutect2
- TENM3 | c.5649C>T p.Y1883= | Silent (SNP) | VAF 31/466 reads (7%) | catalogued as rs760039032, COSV101304955; called by muse, mutect2
- USP15 | c.558C>T p.N186= | Silent (SNP) | VAF 30/280 reads (11%) | catalogued as COSV99738857; called by muse, mutect2, varscan2
